Gene-level copy-number profile of tumor specimen TCGA-G8-6324-01A from TCGA case TCGA-G8-6324, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Intra-abdominal lymph nodes; Age at diagnosis: 43.1 years (15,750 days).
Specimen TCGA-G8-6324-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-DLBC.758d194c-244a-41b7-9e09-1bea5017cefd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G8-6324-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS.
https://portal.gdc.cancer.gov/files/08ae9b87-7b4a-4b62-b9bf-c884a40c0ec6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 286; copy number 1: 1,280; copy number 2: 58,237.

Homozygous deletions (total copy number 0; autosomes only): 286 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:134,838,616–134,902,034, 1 gene (within-gene range 0–1): ACMSD.
- chr2:134,918,235–149,026,759, 142 genes (broad region; genes not listed).
- chr14:105,881,034–106,687,200, 143 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,280. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
